CCDI case PBBIXX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/385ba18a-e585-4a90-a08c-cafe1c65a356

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, benign: ICD-O-3 morphology code: 8000/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.8 years (6,882 days).

Biospecimens (2 samples)
- Sample 0DAEHC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAEHQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
